Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4889, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4889-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4889

Pathology Report

DIAGNOSIS

(A) "SUBCUTANEOUS INVASIVE CYST":

Follicular cyst, infundibular type. (See comment)

(B) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, FUHRMAN'S NUCLEAR GRADE 4 (4.0 CM).

TUMOR CONFINED TO THE KIDNEY.

Margins of resection free of tumor.

Vascular and ureteral margins of resection free of tumor.

One hilar lymph node, no tumor present.

Benign renal cyst.

(C) 11TH RIB:

Segment of rib, gross diagnosis only.

GROSS DESCRIPTION

(A) SUBCUTANEOUS INVASIVE CYST - A tan-pink nodular soft tissue specimen (3.5 x 3.0 x 2.7 cm), consistent with a thin-walled ruptured cyst containing tan cheesy material. Specimen is representatively submitted in A1 and A2. [REDACTED]

(B) LEFT KIDNEY - A nephrectomy specimen (15.0 x 8.5 x 6.5 cm).

A reddish-brown tumor mass (4.0 x 4.0 x 4.0 cm) with yellow areas is present in the mid lateral portion of the kidney. The tumor abuts the renal capsule without apparent involvement of the adipose tissue. It is 0.5 cm from the closest external surface. No renal sinus or renal vein involvement is identified. The remainder of the renal parenchyma has a 0.5 cm cortical cyst. Representative portions of tumor and normal tissue are submitted for tumor banking. The tumor is submitted for electron microscopy.

INK CODE: Black - closest external surface overlying the tumor.

SECTION CODE: B1, renal vein, artery and ureter margins; B2, one hilar lymph node; B3-B13, representative sections of tumor (all yellow areas submitted; B5-B6, have closest external surface); B14, sections of kidney with renal sinus; B15, section of the cortical cyst.

(C) 11TH RIB - A tan-pink non-oriented irregular fragment of rib (3.0 x 1.5 x 0.4 cm). The specimen is entirely submitted for gross only. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 123fc768-27aa-43d6-a2c0-0ceecc3bb8c6 (TCGA-CJ-4889.12C2EB5B-7F9C-4EFE-9523-D9E5D90F4905.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).